Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43C, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43C-01A (Primary Tumor).

[page 1 of 2]
1CD-03

Adenocarcinoma, mucinous
848013

Site:

CecF: esophagus, distal third
C15.5

Path: gastroesophageal junction
C16.0

8-20-12₂₀

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Source of Specimen: Esophagus. History of case: Recently diagnosed with gastroesophageal adenocarcinoma. Operative Procedure/Tissue Submitted: THE distal esophagus and proximal stomach.

PROCEDURE: SPGD

VERIFIED BY:

1. "Distal esophagus proximal stomach" Received in formalin in a large container is a distal esophagus with attached proximal stomach. Esophagus is 10.2 cm in length with the stomach being 8.5 x 4.2 x 2.5 cm. The adventitia is red-tan and ragged with a scant amount of attached yellow adipose. The mucosa of the esophagus is pink-gray and remarkable for fungating ulcerative, tan-gray tumor located at the gastroesophageal junction, but the midpoint is 1.5 cm above the gastroesophageal junction. Tumor is 6.2 cm away from the proximal margin and 3.2 cm away from the distal margin. The tumor has a maximum depth of 0.7 cm and extends to the attached adipose. Tumor is up to 98% circumferential around the gastroesophageal junction. Multiple possible lymph nodes are identified ranging up to 0.6 cm. The adventitia also has a focal area of gray-white small nodules aggregating to 0.5 x 0.3 cm.

1A. Tumor to adjacent proximal.

1B. Tumor to adjacent distal.

1C. Tumor to deep.

1D. Tumor to deep to nodules on adventitia.

1E&F. Tumor at gastroesophageal junction.

1G. Gastroesophageal junction.

1H&I. Multiple possible lymph nodes.

1J. One bisected lymph node.

2. "Cervical esophageal margin" Received in formalin in a small container is a 1.7 cm long x 3.2 cm diameter segment of esophagus. Submucosal hemorrhage is

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

NAME: [REDACTED]
BIRTHDATE: [REDACTED]PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]PAGE #: 3
SEX: [REDACTED]
ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

identified. Shave of the opened end is submitted.

3. "Gastrohepatic ligament LN" Received in formalin in a small container is a 3.0 x 2.1 x 0.6 cm portion of yellow adipose. Two lymph nodes are identified, 0.6 and 1.2 cm.

3A&B. One bisected lymph node each.

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

GASTROESOPHAGEAL JUNCTION CARCINOMAS

Location: Gastroesophageal junction.

Type of Carcinoma: Mucinous.

Precursor Lesions: Unknown.

Depth of Invasion: Subserosa and periesophageal soft tissue.

Number of Positive Lymph Nodes/the Total Number Found: 12/21.

Distant Metastases: Unknown.

Resection Margins Involved: No.

T2b N1 MX

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1-2. Distal esophagus, proximal stomach and cervical esophageal margin, transhiatal esophagectomy: Invasive mucinous carcinoma with prominent signet ring features arising at the gastroesophageal junction and invading through the muscularis propria into the periesophageal soft tissue and coming to within 0.1 cm of the periesophageal soft tissue margin. Proximal and distal margins free of tumor. Vascular invasion present. Metastatic carcinoma in twelve of nineteen lymph nodes (12/19). Extranodal extension present. Please see template.

3. Lymph nodes, gastrohepatic ligament, excision: Two lymph nodes negative for neoplasm (0/2).

Site approved by TC6A 8/11/12 lw

HI/PAI Discrepancy		✓

Source: NCI Genomic Data Commons file 06a62b81-6a07-4765-b783-69c35d5d404c (TCGA-L5-A43C.86D3E142-C83D-47A7-A5C3-58F74CDCB7DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).